Gene-level copy-number profile of tumor specimen ALCH-B36V-TTP1-A from ALCHEMIST case ALCH-B36V, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.2 years (23,459 days).
Specimen ALCH-B36V-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1120e9ab-5d8e-43c4-9f15-39927155df34.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B36V-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/230eca22-0b5a-4b58-b9ed-6fb9ab4b6359

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 529; copy number 1: 10,373; copy number 2: 44,086; copy number 3: 3,026; copy number 4: 517; copy number 5: 151; copy number 6: 210; copy number 7: 16; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:72,814,406–72,843,674, 1 gene (within-gene range 0–2): ATG16L2.
- chr11:85,852,557–85,854,943, 1 gene: AP000974.1.
- chr18:22,088,060–22,098,780, 1 gene: AC091043.1.
- chr20:38,418,483–38,448,215, 9 genes: AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNORA71E.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 379 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,542,325–55,211,628, 10 genes, copy number 6: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1.
- chr14:22,883,222–24,657,774, 117 genes, copy number 5 (broad region; genes not listed).
- chr14:28,829,881–28,968,400, 1 gene, copy number 7 (within-gene range 3–7): LINC02327.
- chr14:28,875,404–35,317,493, 107 genes, copy number 6–7 (broad region; genes not listed).
- chr14:35,388,121–38,041,442, 54 genes, copy number 6 (within-gene range 4–6): AL133163.1, NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4, KRT18P6, INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1.
- chr14:38,605,255–38,948,273, 4 genes, copy number 5: AL357094.1, KRT8P1, LINC00639, AL132994.1.
- chr14:43,540,883–45,290,386, 30 genes, copy number 5: KRT8P2, AL358913.1, ARHGAP16P, LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1, RNU6-552P, DNAJC19P9.
- chr14:49,927,571–51,764,076, 54 genes, copy number 6: LINC01588, MIR6076, PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT, SOS2, L2HGDH, MIR4504, DMAC2L, AL359397.2, CDKL1, AL359397.1, MAP4K5, AL118556.1, Y_RNA, AL118556.2, ATL1, SNRPGP1, SAV1, RN7SL452P, AL606834.1, ZFP64P1, NIN, AL606834.2, AL133485.2, AL133485.1, AL358334.1, PYGL, ABHD12B, AL358334.3, AL358334.2, TRIM9, AL358334.4, AL591770.1, TMX1, SNORA70, Y_RNA, LINC00519, LINC00640, AL358332.1, LINC02310, SETP2, FRMD6-AS2, FRMD6, RNU6-1291P, AL122125.1, FRMD6-AS1, RNA5SP385, RNU6-301P, AL079307.2, OR7E105P, OR7E106P.
- chr22:18,873,543–18,894,407, 2 genes, copy number 11: FAM230F, AC008103.1.

Autosomal genes at a single copy (total copy number 1): 8,034. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
